Gene-level copy-number profile of tumor specimen AP-9LNA-R6 from APOLLO case AP-9LNA, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3.
Specimen AP-9LNA-R6: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0129b604-214c-4fa3-b6c7-4b81c462f8eb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-9LNA-XD (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/5b272a99-fab0-4d96-94df-f2e056952da0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 13,997; copy number 2: 22,415; copy number 3: 19,895; copy number 4: 1,394; copy number 5: 139; copy number 6: 556.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:18,468,336–18,588,747, 6 genes (within-gene range 0–1): TSG101, YWHABP2, AC027544.2, AC027544.1, UEVLD, Metazoa_SRP.
- chr15:34,314,728–34,314,828, 1 gene (within-gene range 0–2): Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 567 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:222,712,553–224,779,335, 45 genes, copy number 5 (within-gene range 4–5): BROX, FAM177B, AL392172.1, DISP1, NDUFB1P2, TLR5, AL359979.2, AL359979.1, SUSD4, RNU4-57P, CCDC185, CAPN8, SNRPEP10, RNU6-1248P, CAPN2, TP53BP2, PHBP11, ACTBP11, CICP5, GTF2IP20, RNU6-1319P, AC138393.1, AC138393.3, AC138393.2, RN7SKP49, FBXO28, AC092809.3, DEGS1, SNORA72, AC092809.2, AC092809.4, NVL, MIR320B2, AC092809.1, RNU6-1008P, CNIH4, WDR26, MIR4742, CNIH3, AKR1B1P1, CNIH3-AS2, DNAJB6P6, AL596330.1, CNIH3-AS1, LINC02813.
- chr10:38,403,189–38,452,153, 1 gene, copy number 5 (within-gene range 3–5): AL133216.2.
- chr10:38,452,987–38,466,176, 2 genes, copy number 5: CICP9, AL133216.1.
- chr12:12,310–3,040,676, 77 genes, copy number 5–6 (broad region; genes not listed).
- chr12:15,882,387–34,249,958, 312 genes, copy number 6 (broad region; genes not listed).
- chr14:30,370,108–32,837,684, 51 genes, copy number 5: AL079305.1, G2E3-AS1, AL117355.1, SYF2P1, G2E3, SCFD1, UBE2CP1, AL121852.1, RPL12P5, AL049830.2, AL049830.1, COCH, AL049830.3, STRN3, HIGD1AP17, MIR624, AL049830.4, AP4S1, HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1, AL139353.2, DTD2, AL163973.1, GPR33, NUBPL, AL163973.3, AL163973.2, RNU6-602P, RNU6-455P, AL355112.1, LINC02313, AL352984.2, AL352984.1, ARHGAP5-AS1, ARHGAP5, AL161665.1, RNU6-7, RNU6-8, AL136298.2, KIAA1143P1, AKAP6, AL136298.1, RN7SL660P, MTCO1P2.
- chr14:33,924,227–37,172,606, 79 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,278. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
